Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1QA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1QA-07A (Additional Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LYMPH NODE, SUBPLEURAL LEFT LOWER LOBE, EXCISION:
One lymph node, negative for tumor (0/1).
- (B) LUNG, LEFT LOWER LOBE, WEDGE RESECTION:
Necrotizing granulomatous inflammation (See comment)
No tumor present.
Background lung parenchyma appears unremarkable.
- (C) LYMPH NODE, LINGULA, EXCISION:
One lymph node, negative for tumor (0/1).
- (D) LYMPH NODE, STATION 9, EXCISION:
Four lymph nodes, negative for tumor (0/4).
- (E) SPLEEN, SPLENECTOMY:
METASTATIC MELANOMA.

ICD-O-3

Melanoma NOS 8720/3

Site:

Spleen C42.2

Jan 11/27/13

COMMENT

- (B) A GMS stain will be performed on the lung granuloma and the results will be reported in an addendum.

GROSS DESCRIPTION

- (A) SUBPLEURAL LN, LEFT LOWER LOBE – Received is a 0.7 x 0.5 x 0.3 cm anthracotic lymph node which is submitted in toto in A.
- (B) LEFT LOWER LOBE WEDGE – Received is an 8.5 x 2.6 x 1.0 cm lung wedge with a staple line margin along the base. The staple line margin is removed and this parenchymal margin is inked black. Section reveals a 1.0 x 1.0 x 1.0 cm well-circumscribed tan-yellow mass 0.6 cm to the parenchymal margin. The remaining parenchyma is spongy tan-red and unremarkable. The mass is submitted entirely.
INK CODE: Blue – pleura; black – parenchymal margin.
SECTION CODE: B1-B2, mass with parenchymal margin, one continuous section; B3, B4, mass with parenchymal margin, one continuous section; B5, uninvolved parenchyma.
- (C) LINGULA NODE – Received is a 2.5 x 1.5 x 0.3 cm piece of spongy tan-yellow soft tissue containing a 0.3 cm in greatest dimension possible anthracotic lymph node. The specimen is serially sectioned and submitted entirely in C.
- (D) STATION 9LN – Received is a 2.5 x 2.0 x 0.5 cm piece of tan-yellow fibroadipose tissue which yields two possible anthracotic lymph nodes measuring 0.6 and 0.8 cm in greatest dimension. Both lymph nodes are submitted entirely.
SECTION CODE: D1, two lymph nodes; D2, remainder of specimen.
- (E) SPLEEN – A spleen (12.5 x 8.0 x 5.0 cm) has tan-brown smooth outer surface. Sectioning reveals a well-circumscribed tan-brown fragile nodule (3.5 x 3.0 x 2.5 cm). The remainder of the spleen consists of tan-red congested splenic parenchyma. SECTION CODE: E1, mass with splenic hilum; E2-E4, mass with splenic parenchyma, representative; E5, normal spleen.

CLINICAL HISTORY

None given.

SNOMED CODES

T-28000, T-C4300, M-Y3220, T-C3000, M-87206

"Some tests reported here may have been developed and performance characteristics determined by not been specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have

Entire report and diagnosis completed by:

[page 2 of 2]
ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

COMMENT

On part (B), a GMS stain shows the presence of structures suggestive of fungal elements. Close clinical correlation and tissue cultures are highly recommended.

Entire report and diagnosis completed by

-----END OF REPORT-----

Additional met to [initial met]

Source: NCI Genomic Data Commons file d1973174-4418-46f9-a707-c4e5ac4e2d02 (TCGA-D3-A1QA.0895B97D-2BB1-4E6E-A59F-AAE9579B46EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).